Somatic mutation profile of tumor specimen C3L-00583-01 (aliquot CPT0019130006) from CPTAC case C3L-00583, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.4 years (20,237 days).
Specimen C3L-00583-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f329c19f-6bd6-4ab9-a2d5-25146493b5f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00583-31 (Blood Derived Normal), aliquot CPT0019900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56c9fadc-b75f-4b32-9d99-f0a7b6fe5548

The open-access MAF lists 63 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 11, Intron 4, Frame Shift Del 4, Splice Site 2, Frame Shift Ins 2, 5'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 120/282 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs5030811, CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- ADAMTS12 | c.3860A>C p.E1287A | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.211); catalogued as rs1404984152, COSV100710369; called by muse, mutect2, varscan2
- CSMD2 | c.5636C>A p.S1879Y | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53962655; called by muse, mutect2, varscan2
- DNAH17 | c.13157C>T p.T4386I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs766337802; called by muse, mutect2, varscan2
- FUT6 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as COSV54606589; called by muse, mutect2, varscan2
- GCNT2 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 173/538 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs143453847; called by muse, mutect2, varscan2
- GNRHR | c.869A>T p.Y290F | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1111643; called by muse, mutect2, varscan2
- KDM5C | c.1903del p.R635Gfs*24 | Frame Shift Del (DEL) | VAF 103/230 reads (45%) | catalogued as COSV104428137; called by mutect2, pindel, varscan2
- NPSR1 | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs149663215; called by muse, mutect2, varscan2
- PPWD1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs550297856, COSV54333431; called by muse, varscan2
- UBA7 | c.2823G>T p.L941F | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs865842611; called by muse, mutect2
- ZNF581 | c.538C>G p.R180G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.667); catalogued as rs778131710; called by muse, mutect2, varscan2
- ZNF787 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1174903192; called by muse, mutect2
- ACACB | c.1630T>C p.F544L | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATE1 | c.1461del p.K487Nfs*60 | Frame Shift Del (DEL) | VAF 36/183 reads (20%) | called by mutect2, pindel, varscan2
- BBOF1 | c.187del p.S63Vfs*5 | Frame Shift Del (DEL) | VAF 41/171 reads (24%) | called by mutect2, pindel, varscan2
- BLOC1S3 | c.409C>A p.R137S | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- BRWD1 | c.56A>T p.Y19F | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- BTG4 | c.202A>C p.K68Q | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CAPRIN2 | c.2233T>C p.F745L | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CSE1L | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CYP51A1 | c.549dup p.E184Rfs*7 | Frame Shift Ins (INS) | VAF 68/351 reads (19%) | called by pindel, varscan2
- CYP51A1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 72/351 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, varscan2
- DNAJB13 | c.167G>C p.S56T | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DRICH1 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FANCM | c.1432dup p.R478Pfs*11 | Frame Shift Ins (INS) | VAF 82/304 reads (27%) | called by pindel, varscan2
- FBN3 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- GBP5 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- GCN1 | c.7563+1G>A p.X2521_splice | Splice Site (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- GOLGA8J | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 59/590 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- GREB1 | c.4861G>A p.E1621K | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- HMGCR | c.141T>G p.N47K | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- IMPG1 | c.1762A>C p.N588H | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- IPO9 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 160/552 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LINC02868 | n.87-1G>T | Splice Site (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- MTREX | c.559_562del p.F187Pfs*7 | Frame Shift Del (DEL) | VAF 24/89 reads (27%) | called by mutect2, pindel, varscan2
- NOTCH4 | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PBRM1 | c.2264T>A p.V755D | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- PCDHB10 | c.1941T>A p.N647K | Missense Mutation (SNP) | VAF 247/835 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PDS5A | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2
- SPEG | c.7274G>C p.R2425P | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TFAM | c.178T>A p.F60I | Missense Mutation (SNP) | VAF 116/446 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMEM131 | c.3836A>T p.K1279M | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- VWA8 | c.5639C>G p.S1880C | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- WDR86 | c.306G>T p.R102S | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ADORA2A | c.807C>A p.L269= | Silent (SNP) | VAF 82/238 reads (34%) | called by muse, mutect2, varscan2
- DNAI3 | c.1428T>C p.N476= | Silent (SNP) | VAF 72/259 reads (28%) | catalogued as rs1225726526; called by muse, mutect2, varscan2
- EBAG9 | c.132T>C p.T44= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as rs1312285780; called by muse, mutect2, varscan2
- GPC4 | c.684G>A p.A228= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs757883865; called by muse, mutect2
- KRT15 | c.288C>T p.G96= | Silent (SNP) | VAF 73/274 reads (27%) | catalogued as rs768785185; called by muse, mutect2, varscan2
- MUC5AC | c.14839C>T p.L4947= | Silent (SNP) | VAF 132/434 reads (30%) | called by muse, mutect2, varscan2
- MYCBP2 | c.5061T>C p.A1687= (on ENST00000357337; = p.A1725= on NM_015057.5) | Silent (SNP) | VAF 103/423 reads (24%) | called by muse, mutect2, varscan2
- PCF11 | c.4653A>G p.T1551= | Silent (SNP) | VAF 43/136 reads (32%) | called by muse, mutect2, varscan2
- TIMD4 | c.378C>T p.N126= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as rs761841993; called by muse, varscan2
- TNKS | c.870T>C p.A290= | Silent (SNP) | VAF 51/222 reads (23%) | called by muse, mutect2, varscan2
- UNC13B | c.4206C>T p.I1402= | Silent (SNP) | VAF 36/135 reads (27%) | called by muse, mutect2, varscan2
- ATL2 | c.118+1025T>A | Intron (SNP) | VAF 20/70 reads (29%) | catalogued as rs143781075; called by muse, mutect2, varscan2
- DNAH14 | c.2938+1982A>G | Intron (SNP) | VAF 88/280 reads (31%) | called by muse, mutect2, varscan2
- ERLIN2 | chr8:37736077 A>T | 5'Flank (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- HSPB1 | c.-14C>T | 5'UTR (SNP) | VAF 162/802 reads (20%) | called by muse, mutect2, varscan2
- NACA | c.71-2028G>A | Intron (SNP) | VAF 11/35 reads (31%) | catalogued as COSV63271385; called by muse, mutect2
- OPLAH | c.2512-33C>T | Intron (SNP) | VAF 104/352 reads (30%) | catalogued as rs1279438708; called by muse, mutect2, varscan2
- SPATA31C2 | n.1939del | RNA (DEL) | VAF 133/648 reads (21%) | called by mutect2, pindel, varscan2
